FM case AD14829 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Small intestine.
https://portal.gdc.cancer.gov/cases/d6387325-53c8-4bd2-ae91-b8eb8a199d73

Female, 46.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the duodenum; metastasis biopsied or resected from the pancreas. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
